MMRF case MMRF_1781 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/dde52f03-3a3f-4c39-92dd-02ebf1610481

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.4 years (25,345 days); ISS stage: II; Days to last known disease status: 1,101 days (3.0 years); Days to last follow up: 1,101 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 60 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 87 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 106 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 107 days; Days to treatment end: 107 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 295 days; Days to treatment end: 298 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 297 days; Days to treatment end: 297 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 299 days; Days to treatment end: 299 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -26 (ECOG 1): M Protein 2.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 5.04 g/L; Immunoglobulin A 44.5 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 3.69 µg/mL; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 32 g/L; Total Protein 8.5 g/dL; Glucose 5.94 mmol/L.
- Day 79 (ECOG 1): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 7.16 g/L; Immunoglobulin A 3.17 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 8.3 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 274 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.5 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL; Glucose 5.56 mmol/L.
- Day 148 (ECOG 1): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.43 mg/dL; Immunoglobulin G 6.35 g/L; Immunoglobulin A 1.56 g/L; Immunoglobulin M 1.43 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 43.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 5.56 mmol/L.
- Day 240 (ECOG 0): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 7.61 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.34 mmol/L.
- Day 327 (ECOG 1): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.491 mg/dL; Immunoglobulin G 4.64 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.89 µg/mL; Lactate Dehydrogenase 12.7 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 5.1 g/dL; Glucose 7.04 mmol/L.
- Day 415 (ECOG 1): M Protein 0.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 5.27 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 1.18 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 4.95 mmol/L.
- Day 513 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 7.01 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.53 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 4.84 mmol/L.
- Day 611 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 7.4 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 1.26 g/L; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 4.62 mmol/L.
- Day 695 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 7.08 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 1.04 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 5.01 mmol/L.
- Day 786 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.21 mg/dL; Immunoglobulin G 8.3 g/L; Immunoglobulin A 1.57 g/L; Immunoglobulin M 1.15 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 5.94 mmol/L.
- Day 898 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.17 mg/dL; Immunoglobulin G 8.89 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 1.08 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 8.03 mmol/L.
- Day 989 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 8.86 g/L; Immunoglobulin A 2.06 g/L; Immunoglobulin M 1.31 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 6.38 mmol/L.
- Day 1,101 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 8.81 g/L; Immunoglobulin A 2.28 g/L; Immunoglobulin M 1.29 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.55 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 7.43 mmol/L.

Other clinical attributes
- Day -26: Weight: 50 kg; Height: 147 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1781_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -26 days.
- Sample MMRF_1781_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -26 days.
